FM case AD4181 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/14d4136f-222e-40a2-b4b9-7b04f9828f3c

Male, 75.1 years: Gastrointestinal stromal tumor, NOS (ICD-O-3 8936/1) of the gastrointestinal tract; metastasis biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
